Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92X, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92X-01A (Primary Tumor).

[page 1 of 3]
Patient Name:.

MRN:

DOB:

Gender:M

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: thymus gland and thymoma; long stitch on left upper pole;
short stitch on right pleura

ICD 8-3

Thymoma, type B2, malignant
8584/3

DIAGNOSIS

Thymus and thymic tumor, resection:

- Thymoma, WHO type B2, 7 cm in greatest diameter.
- Encapsulated with focal tumor extension into capsule. (See comment)
- No invasion of visceral pleural.
- Painted resection margins negative for tumor.

Date Thymus

C37.9

854/2/14

SYNOPTIC DATA

Specimen Type:
visceral pleura

Specimen Size:

Tumor Site:

Tumor Size:

Other: Resection of thymic mass with

Greatest dimension: 12.8 cm

Anterior mediastinum

Greatest dimension: 7 cm

Additional dimensions: 6 x 2.8 cm

Type B thymoma, B2 (cortical)

Stage IIa: Microscopic transcapsular

Histologic Type:

Pathologic Staging:

invasion

Regional Lymph Nodes:

Distant Metastasis:

Margins:

Invasion of Pulmonary Parenchyma:

Pleural Invasion:

Vascular (Small/Large Vessel) Invasion:

pNX: Cannot be assessed

Cannot be assessed

Margins uninvolved by tumor

Absent

Absent

Absent

COMMENT

Status: complete

Page: 1 of 3

[page 2 of 3]
Department of Pathology

Patient Name

MRN:

Service:

Collected:

DOB:

Visit #:

Resulted:

Gender:M

Location:

Facility:

Ordering MD:

The tumor is mostly encapsulated but focally it appears to lack a capsule or has into and extended through the capsule. This is evident mainly in the subpleural area. At non-pleural aspects, a thin layer of mobile fibromembranous or fibroadipose tissue covers the tumor. All painted resection margins sampled for histological examination are free of tumor. Thus, the tumor appears completely excised.

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

myasthenia gravis

GROSS DESCRIPTION

The specimen is labeled with the patient's name and as "thymus: Thymus gland and thymoma; long stitch on left upper pole; short stitch on right pleura".

Resection specimen: Thymectomy weighing 118.0 g and measuring 12.8 cm SI x 15.0 cm ML x 2.9 cm AP, with portion of right pleura measuring 8.5 cm SI x 7.5 cm ML attached to the posterior surface. On the side opposite the pleura, there is a thin but mobile fibrous tissue covering the mass within the specimen. The specimen is painted with silver nitrate.

Pleural surface: smooth

Number of tumors: 1

Measurements: 7.0 cm SI x 6.0 cm ML x 2.8 cm AP.

Location: Within mid and right thymus gland

Distance from resection margins:

0.1 cm from the anterior thymus margin

0.2 cm from the posterior right pleural margin

0.4 cm from the mid superior thymus margin

6.3 cm from the right superior thymus lobe margin

0.4 cm from the inferior thymus margin

0.1 cm from the right lateral thymus margin

2.7 cm from the left lateral fundus margin

Descriptive characteristics: Tan color; somewhat friable consistency with focal microcystic changes; well delineated, with a lobulated parenchyma and pale, fibrous-appearing septae separating tumor lobules

Thymus parenchyma uninvolved by tumor:

The uninvolved left thymus is edematous and congested. The uninvolved right superior lobe is grossly unremarkable.

[page 3 of 3]
Department of Pathology

Patient Name:

MRN:

DOB:

Gender:M

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Other lesions: No other nodules or masses are identified.

Lymph Nodes: No lymph nodes are identified.

Frozen Section: No

Tissue Banking: The tumor (five pieces) and normal thymus (two pieces) are sampled for tissue banking

Representative sections are submitted as follows:

1A tumor, with anterior thymus margin

1B-1C tumor, with posterior pleural margin

1D tumor, with mid superior thymus margin

1E tumor, with inferior thymus margin

1F tumor, with right lateral thymus margin

1G left lateral thymus margin

1H-1I tumor

1J-1K left thymus

1L superior lobe right thymus

1M an additional block of tumor under the pleura

MICROSCOPIC DESCRIPTION

Sections reveal a circumscribed and almost entirely encapsulated tumour composed of mixed population of small lymphocytes and larger cells with nuclei displaying open chromatin pattern and prominent nucleoli. The tumor shows focal microcystic changes. Immunohistochemical stains showed diffuse positive staining of the larger cells for CK5/6, while a majority of the lymphocytes are CD1a positive. The immunohistochemical profile is consistent with a thymoma.

Source: NCI Genomic Data Commons file 17ae6363-004d-42a1-a80a-1901d9942b24 (TCGA-XU-A92X.4DC88376-0D34-412D-A2D2-CF1331996D84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).